Gene-level copy-number profile of tumor specimen TCGA-FS-A1ZG-06A from TCGA case TCGA-FS-A1ZG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.1 years (22,329 days).
Specimen TCGA-FS-A1ZG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.dff30a92-8ee8-4c61-a8f2-04a7437a945e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A1ZG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6e8703c1-83ee-43d9-998d-f9ff276157a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 5,842; copy number 2: 50,109; copy number 3: 3,639; copy number 4: 91; copy number 5: 109; copy number 6: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A1ZG-06A-11D-A191-01): tumor purity 1, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,522,666–181,591,969, 2 genes: AC093840.1, AC093840.2.
- chr5:112,827,213–112,867,582, 1 gene (within-gene range 0–2): AC008575.1.
- chr22:33,725,007–33,750,843, 1 gene (within-gene range 0–1): LARGE-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 132 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:2,712,591–2,967,955, 7 genes, copy number 5 (within-gene range 3–5): LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2.
- chr5:5,140,330–5,320,304, 1 gene, copy number 5 (within-gene range 3–5): ADAMTS16.
- chr5:5,375,723–5,376,836, 1 gene, copy number 5: ALG3P1.
- chr5:7,396,138–7,925,398, 6 genes, copy number 5 (within-gene range 1–5): ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3, AC025174.1.
- chr5:9,035,033–9,546,075, 1 gene, copy number 5 (within-gene range 1–5): SEMA5A.
- chr5:9,363,275–9,422,481, 1 gene, copy number 5 (within-gene range 1–5): AC091906.1.
- chr5:10,761,065–10,777,062, 2 genes, copy number 5: AC012629.2, AC012629.1.
- chr5:16,615,926–17,387,310, 20 genes, copy number 5: AC024588.1, AC022113.1, Y_RNA, MYO10, RNA5SP179, RPS26P28, RNU6-660P, BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111.
- chr5:17,684,584–18,236,196, 3 genes, copy number 5 (within-gene range 3–5): LINC02223, RPL36AP21, SNORD81.
- chr6:65,788,417–66,728,904, 5 genes, copy number 5: SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr22:38,032,165–39,155,945, 62 genes, copy number 5 (broad region; genes not listed).
- chr22:40,346,500–41,045,591, 23 genes, copy number 6: ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1, SLC25A17, Z98048.1, JTBP1, MIR4766, ST13, XPNPEP3, DNAJB7, Metazoa_SRP, RNU6-379P, RBX1, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 4,920. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
